Somatic mutation profile of tumor specimen TCGA-78-7167-01A (aliquot TCGA-78-7167-01A-11D-2063-08) from TCGA case TCGA-78-7167, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.5 years (28,295 days).
Specimen TCGA-78-7167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 115a1cb7-19e4-40d3-b239-c019fbc78a15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7167-11A (Solid Tissue Normal), aliquot TCGA-78-7167-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35b78980-8e78-4d69-881e-66188ec1e6b3

The open-access MAF lists 104 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 26, Nonsense Mutation 7, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, In Frame Del 1, 5'UTR 1, Intron 1, Splice Region 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 43/52 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260583; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC11 | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.354); catalogued as COSV62321103; called by muse, mutect2, varscan2
- ACACB | c.4147G>C p.D1383H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV58127613, COSV58149161; called by muse, mutect2, varscan2
- ADGRE5 | c.1014G>C p.M338I (on ENST00000242786 / NM_078481.4; = p.M245I on NM_001784.5) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54408060; called by muse, mutect2, varscan2
- AHCTF1 | c.5575G>T p.E1859* (on ENST00000366508; = p.E1833* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as COSV100404305; called by muse, mutect2, varscan2
- AMPD3 | c.942G>A p.V314= (on ENST00000396553 / NM_001025389.2; = p.V323= on NM_000480.3) | Splice Region (SNP) | VAF 33/175 reads (19%) | catalogued as COSV67329787; called by muse, mutect2, varscan2
- APOB | c.11299G>A p.E3767K | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.185); catalogued as COSV51922034; called by muse, mutect2, varscan2
- ARFGEF3 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.494); catalogued as COSV52449600; called by muse, mutect2, varscan2
- ARID1A | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61370891, COSV61373674; called by muse, mutect2, varscan2
- BNIP2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV51104988; called by muse, mutect2, varscan2
- C1orf131 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV59642144; called by muse, mutect2, varscan2
- CA11 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50032707; called by muse, mutect2, varscan2
- CCDC178 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs745408194, COSV55757647; called by muse, mutect2, varscan2
- CCR6 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV59473754; called by muse, mutect2, varscan2
- CHAF1A | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56670049; called by muse, mutect2, varscan2
- CHORDC1 | c.887C>G p.T296S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV57705097; called by muse, mutect2, varscan2
- CLEC2B | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs771674688, COSV57308579, COSV99947008; called by muse, mutect2, varscan2
- CNTNAP5 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV70470676; called by muse, mutect2, varscan2
- COG3 | c.473T>C p.L158S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63071167; called by muse, mutect2, varscan2
- DCUN1D2 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 42/172 reads (24%) | catalogued as COSV60260588; called by muse, varscan2
- DNAH9 | c.4170G>A p.M1390I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV99307670; called by muse, mutect2
- DPF1 | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV62791948; called by muse, mutect2, varscan2
- FGF12 | c.519G>A p.W173* (on ENST00000454309 / NM_021032.5; = p.W111* on NM_004113.6) | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | catalogued as COSV53150705; called by muse, mutect2, varscan2
- FSCB | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV61216399; called by muse, mutect2, varscan2
- FSD1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 10/13 reads (77%) | catalogued as COSV55694426; called by muse, mutect2, varscan2
- HACD2 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67322021; called by muse, mutect2, varscan2
- HOMER1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs1335189835, COSV56523377; called by muse, varscan2
- INSC | c.83G>T p.R28M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV65408594; called by muse, mutect2, varscan2
- INSC | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65408600; called by muse, mutect2, varscan2
- ISLR2 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62301559; called by muse, mutect2, varscan2
- KCNJ10 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63632770; called by muse, mutect2, varscan2
- LRP2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55539624, COSV99785979; called by muse, mutect2, varscan2
- MARK2 | c.1089C>G p.Y363* | Nonsense Mutation (SNP) | VAF 29/51 reads (57%) | catalogued as COSV59280152; called by muse, mutect2, varscan2
- MFAP4 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55189161; called by muse, mutect2, varscan2
- MYO18B | c.6635C>A p.A2212D | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100124910; called by muse, mutect2, varscan2
- MYO1B | c.2103G>T p.K701N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58426739; called by muse, mutect2, varscan2
- MYO5C | c.4048G>A p.D1350N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV55902249; called by muse, mutect2, varscan2
- NETO1 | c.293T>G p.F98C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55001047; called by muse, mutect2, varscan2
- NKTR | c.3598A>T p.S1200C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as rs946685188, COSV51769131; called by muse, mutect2, varscan2
- OR1K1 | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV52956062; called by muse, mutect2, varscan2
- OSBPL10 | c.2058G>T p.K686N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV67335806; called by muse, mutect2, varscan2
- PAPPA2 | c.5087C>G p.T1696S | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV62790115, COSV62792538; called by muse, mutect2, varscan2
- PCDHGA1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65294812, COSV65300168; called by muse, mutect2, varscan2
- PNLIPRP1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.752); catalogued as rs782187986, COSV62610621, COSV62610657; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1697C>A p.T566K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV62782006; called by muse, mutect2, varscan2
- RIDA | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201559618, COSV54703768; called by muse, mutect2, varscan2
- ROCK1 | c.2837G>A p.S946N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs377651671; called by muse, mutect2, varscan2
- RTEL1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58890401; called by muse, mutect2, varscan2
- RYR1 | c.1662G>T p.E554D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100616748; called by muse, mutect2, varscan2
- RYR3 | c.13324G>A p.E4442K (on ENST00000389232; = p.E4443K on NM_001036.6) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as COSV66776765; called by muse, mutect2, varscan2
- SALL1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV51752796; called by muse, mutect2, varscan2
- SDK1 | c.5233G>C p.D1745H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV67355454; called by muse, mutect2, varscan2
- SIAH2 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs753923640, COSV57261578; called by muse, mutect2, varscan2
- SIAH3 | c.313T>C p.C105R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV68551207; called by muse, mutect2, varscan2
- SLC2A13 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV55126018, COSV99787000; called by muse, mutect2, varscan2
- SMC2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53954780; called by muse, mutect2, varscan2
- SPIN1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV65498556; called by muse, mutect2
- STAP1 | c.855T>A p.S285R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55326051; called by muse, mutect2, varscan2
- TAF1L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54256483; called by muse, mutect2, varscan2
- TBC1D5 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV53748412, COSV99510906; called by muse, mutect2, varscan2
- TMEM132D | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70593116; called by muse, mutect2, varscan2
- TMPRSS11F | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV62464306; called by muse, mutect2, varscan2
- TRPV4 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV55679574; called by muse, mutect2, varscan2
- TTLL7 | c.89G>T p.R30M | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV53081092; called by muse, mutect2, varscan2
- UBE2E2 | c.555A>C p.R185S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59965084; called by muse, mutect2, varscan2
- ZFP36L1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV60544191, COSV60544799; called by muse, mutect2, varscan2
- ZNF804B | c.2249T>C p.V750A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs143293437; called by muse, mutect2, varscan2
- EYA1 | c.320_329del p.A107Gfs*131 | Frame Shift Del (DEL) | VAF 21/139 reads (15%) | called by mutect2, pindel
- HEG1 | c.2904dup p.A969Cfs*53 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- PTTG2 | c.337_348del p.E113_K116del | In Frame Del (DEL) | VAF 34/179 reads (19%) | called by mutect2, pindel, varscan2
- ZNF592 | c.635del p.L212Wfs*63 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- ACTC1 | c.720G>A p.K240= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as COSV51757287; called by mutect2, varscan2
- ATAD3A | c.1677C>T p.Y559= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs374773488, COSV59231559; called by muse, varscan2
- C16orf89 | c.426C>G p.S142= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60122070; called by muse, mutect2, varscan2
- CHD8 | c.5823G>T p.G1941= (on ENST00000646647 / NM_001170629.2; = p.G1662= on NM_020920.4) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV63036394; called by muse, mutect2, varscan2
- CUEDC1 | c.474G>A p.A158= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs200050222, COSV64225984; called by muse, mutect2, varscan2
- DIPK1B | c.537C>G p.L179= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV63037689; called by muse, mutect2, varscan2
- EVC2 | c.2334G>A p.E778= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1185267231, COSV60387396; called by muse, mutect2, varscan2
- EYS | c.1386A>T p.G462= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV60975742; called by muse, mutect2, varscan2
- LRP1B | c.11922T>C p.I3974= | Silent (SNP) | VAF 22/161 reads (14%) | catalogued as rs1241289771, COSV67183551; called by muse, mutect2, varscan2
- MADD | c.4554G>A p.L1518= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1335499997, COSV60620060; called by muse, mutect2, varscan2
- MYO18B | c.6636C>T p.A2212= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as rs760987427, COSV59135355, COSV59139033; called by muse, mutect2, varscan2
- OR8H2 | c.234C>T p.V78= | Silent (SNP) | VAF 113/560 reads (20%) | catalogued as COSV57943041; called by muse, mutect2, varscan2
- PDIA5 | c.1062G>A p.T354= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as rs372369512; called by muse, mutect2, varscan2
- PITPNM3 | c.1041C>T p.T347= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs755403167, COSV52592731; called by muse, mutect2, varscan2
- PLCXD1 | c.912C>T p.I304= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs778051898, COSV58204335, COSV58206056; called by muse, mutect2, varscan2
- PLPPR3 | c.1620C>T p.I540= (on ENST00000520876 / NM_001270366.2; = p.I568= on NM_024888.2) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs770993490, COSV62458552; called by muse, varscan2
- RHBDL1 | c.1281C>T p.Y427= (on ENST00000219551 / NM_001318733.2; = p.Y362= on NM_001278720.2) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs558802175, COSV53482812; called by muse, mutect2, varscan2
- RUVBL1 | c.72G>A p.L24= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59474835; called by muse, mutect2, varscan2
- RYR1 | c.2544C>T p.T848= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs140374285; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRD5A3 | c.375G>A p.L125= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs1366325847, COSV51710811; called by muse, mutect2, varscan2
- TNN | c.3897C>T p.F1299= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV53421067; called by muse, mutect2, varscan2
- UBXN2B | c.117G>A p.V39= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV68308527; called by muse, mutect2, varscan2
- WDFY2 | c.783C>T p.G261= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs1343863779, COSV53286863; called by muse, mutect2, varscan2
- WDR1 | c.1260C>T p.Y420= (on ENST00000382452; = p.Y280= on NM_005112.5) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs368099158, COSV66723031; called by muse, mutect2, varscan2
- ZFC3H1 | c.330C>T p.F110= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV57347849; called by muse, mutect2, varscan2
- ZNF536 | c.2238G>T p.L746= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as COSV62817720; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840836 C>T | 5'Flank (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100005834, COSV100007453, COSV100007872; called by muse, mutect2, varscan2
- MTUS1 | c.2624-12819A>T | Intron (SNP) | VAF 39/127 reads (31%) | catalogued as COSV99870566; called by muse, mutect2, varscan2
- OSCAR | c.*352C>T | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99500068; called by muse, mutect2, varscan2
- RBAK | c.-49G>T | 5'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100806742; called by muse, mutect2, varscan2
- RPL23AP42 | n.198C>G | RNA (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
